Somatic mutation profile of tumor specimen TCGA-EB-A44Q-06A (aliquot TCGA-EB-A44Q-06A-11D-A25O-08) from TCGA case TCGA-EB-A44Q, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 51.8 years (18,932 days).
Specimen TCGA-EB-A44Q-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f7209d97-ce1e-4bbc-8562-ef64668198c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A44Q-10A (Blood Derived Normal), aliquot TCGA-EB-A44Q-10A-01D-A25O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c85275fc-575c-4245-878e-70a0fca292f9

The open-access MAF lists 48 somatic variants for this specimen: 38 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 31, Silent 10, Nonsense Mutation 4, Splice Region 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.6118C>T p.R2040* | Nonsense Mutation (SNP) | VAF 16/57 reads (28%) | catalogued as rs61753038, CM032170, COSV64674774; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- LCE1F | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 25/91 reads (27%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.756); catalogued as rs202168792, COSV57669605; called by muse, mutect2, varscan2
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 53/122 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC005324.2 | c.953C>G p.T318S | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.898); catalogued as COSV60888416; called by muse, mutect2, varscan2
- ADAMTS16 | c.691C>T p.Q231* | Nonsense Mutation (SNP) | VAF 127/166 reads (77%) | catalogued as COSV56996280, COSV57006645; called by muse, mutect2, varscan2
- CBL | c.1246T>A p.C416S | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50635032, COSV50641130; called by muse, mutect2, varscan2
- CIC | c.2774C>G p.P925R | Missense Mutation (SNP) | VAF 55/155 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV50662770; called by muse, mutect2, varscan2
- DCAF11 | c.1273G>A p.D425N | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.382); catalogued as COSV58110693; called by muse, mutect2, varscan2
- DGKH | c.1807G>A p.V603I | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs201254895, COSV54935763; called by muse, mutect2, varscan2
- DGKI | c.553G>A p.V185I | Missense Mutation (SNP) | VAF 31/226 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.04); catalogued as rs779164061, COSV55950318; called by muse, mutect2, varscan2
- DOT1L | c.1250T>G p.M417R | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.201); catalogued as COSV101288766; called by muse, mutect2, varscan2
- DSG3 | c.2959A>G p.T987A | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as rs1158935763, COSV57129573; called by muse, mutect2, varscan2
- EPHA8 | c.821T>C p.V274A | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as COSV51297938; called by muse, mutect2, varscan2
- IRAG1 | c.1672G>T p.A558S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV70212981; called by muse, mutect2
- ITGAD | c.1807G>T p.V603L | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as COSV66758266, COSV66760121; called by muse, mutect2, varscan2
- KRT78 | c.559T>A p.L187M | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58853531; called by muse, varscan2
- KRT78 | c.481G>C p.V161L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV58853538; called by muse, varscan2
- MYH11 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1555459204, COSV55569204; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OASL | c.193G>C p.V65L | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV57479891, COSV57479921; called by muse, mutect2, varscan2
- OTOF | c.3079G>A p.D1027N (on ENST00000272371 / NM_194248.3; = p.D280N on NM_004802.4) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as COSV55518942; called by muse, mutect2, varscan2
- PALMD | c.369T>C p.S123= | Splice Region (SNP) | VAF 7/33 reads (21%) | catalogued as rs761060318, COSV54166909; called by muse, mutect2
- PAN2 | c.652-1G>A p.X218_splice | Splice Site (SNP) | VAF 52/140 reads (37%) | catalogued as COSV57756062; called by muse, mutect2, varscan2
- PPWD1 | c.1094A>G p.E365G | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.344); catalogued as COSV54335610; called by muse, mutect2, varscan2
- RIOX2 | c.661G>C p.V221L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as COSV57724909; called by muse, mutect2, varscan2
- RPL11 | c.94C>A p.L32M (on ENST00000374550 / NM_001199802.1; = p.L33M on NM_000975.5) | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV65779041; called by muse, mutect2, varscan2
- SEMA4A | c.984G>A p.W328* | Nonsense Mutation (SNP) | VAF 12/48 reads (25%) | catalogued as COSV61774009; called by muse, mutect2, varscan2
- SLC2A4 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV50302367; called by muse, mutect2, varscan2
- SLC38A4 | c.233G>A p.G78E | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56965388; called by muse, mutect2, varscan2
- SLC7A13 | c.563A>G p.E188G | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52537144; called by muse, mutect2, varscan2
- TMPRSS2 | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV59827357; called by muse, mutect2, varscan2
- TP53I13 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.558); catalogued as rs545614632, COSV56404034; called by muse, mutect2, varscan2
- TRIO | c.5997G>T p.M1999I | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.97); catalogued as COSV60095187; called by muse, mutect2
- USP34 | c.9448C>G p.H3150D | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101277251, COSV68406398; called by muse, mutect2, varscan2
- USP7 | c.1900C>T p.R634* | Nonsense Mutation (SNP) | VAF 5/27 reads (19%) | catalogued as COSV61217433; called by muse, mutect2, varscan2
- ZACN | c.946G>A p.G316R | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.521); catalogued as COSV58037839; called by muse, mutect2, varscan2
- ZNF28 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.931); catalogued as COSV60425317; called by muse, mutect2, varscan2
- ZNF711 | c.1175T>G p.F392C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52158914; called by muse, mutect2, varscan2
- GSTT2 | c.128dup p.E44Gfs*18 | Frame Shift Ins (INS) | VAF 15/67 reads (22%) | called by mutect2, pindel, varscan2
- ATP6V0A2 | c.1375C>T p.L459= | Silent (SNP) | VAF 15/290 reads (5%) | catalogued as COSV57752155; called by muse, mutect2
- AVIL | c.1842C>A p.V614= | Silent (SNP) | VAF 33/764 reads (4%) | catalogued as COSV57683773; called by muse, mutect2
- CA2 | c.782A>G p.*261= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV53408287; called by muse, mutect2, varscan2
- DTD1 | c.279C>T p.F93= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV66282137; called by muse, mutect2, varscan2
- GCN1 | c.5712C>A p.S1904= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as COSV56114607; called by muse, mutect2, varscan2
- GCN1 | c.5004C>T p.D1668= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV56114617; called by muse, varscan2
- HCN1 | c.2019G>T p.L673= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV57509834, COSV57536510; called by muse, mutect2, varscan2
- LHFPL2 | c.246C>T p.C82= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV66716301; called by muse, mutect2, varscan2
- RNF215 | c.678C>T p.L226= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV53177038; called by muse, mutect2, varscan2
- TLL1 | c.1963A>C p.R655= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV50263459, COSV50321640; called by muse, mutect2, varscan2
